Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QF, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QF-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

year old female with 2.9 cm right thyroid lobe nodule.

Specimens Submitted:

1: Total thyroidectomy

DIAGNOSIS:

1. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.9 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

A separate focus of papillary microcarcinoma is noted in the left lobe measuring 0.2 cm in greatest dimension

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

ICB-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 per 3/16/11

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Total thyroidectomy" and consists of a thyroid weighing 28 grams. The right lobe measures 4.5 x 3.5 x 3 cm, the left lobe measures 4.0 x 2.3 x 1.2 cm and the isthmus measures 2.2 x 2.0 x 0.7 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals, in the right lobe, a well-circumscribed, soft, markedly hemorrhagic, gelatinous brown-tan nodule measuring 2.9 x 2.6 x 2.5 cm. It abuts the capsular surface but does not grossly involve or extend through it. Sections through the remaining tissue reveals, in the left lobe, a well-circumscribed, firm, brown-tan nodule measuring 1.0 x 0.7 x 0.6 cm. It abuts the capsular surface but does not grossly involve or extend through it. The remaining thyroid parenchyma is red tan and meaty. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted from left to right.

Summary of sections:

RL-serial section of right lobe, bisected

RL - right lobe

LL - left lobe

I - isthmus

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
2	I	2
3	LL	3
5	RL	5
2	RLB	2

Source: NCI Genomic Data Commons file ce62297a-e16a-44b6-900f-64ecddea1784 (TCGA-DJ-A1QF.256268EC-7FD9-4296-BFE0-72D78B04269C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).